Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4V4, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4V4-01A (Primary Tumor).

[page 1 of 2]
Neck
Neck

Clinical Diagnosis & History:

Papillary thyroid carcinoma right thyroid, biopsy (positive).

Specimens Submitted:

1: Total thyroid

DIAGNOSIS:

1. Total thyroid:

Part # 1

Tumor Type:

Papillary microcarcinoma, two foci

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Right lobe

Tumor Size:

Greatest diameter is 0.9 cm.
for right lobe nodule and 0.1 cm for left lobe nodule.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

ICD-0-3

carcinoma, papillary, tall cell variant

8344/3

Site: Thyroid, NOS C73.9

hw
10/31/12

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out **

Gross Description:

1). The specimen is received fresh, labeled "total thyroid, stitch marks right superior pole" and consists of a thyroid weighing 14.0 g. The right lobe measures 3.9 x 2.4 x 1.6 cm, the left lobe measures 4.5 x 2.5 x 1.5 cm and the isthmus measures 2.9 x 1.4 x 1.2 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a white-tan circumscribed rubbery nodule measuring 0.9 x 0.8 x 0.6 cm in the right middle lobe, abutting the anterior and posterior margins. Sectioning of the tissue reveals a second firm circumscribed nodule measuring 0.5 cm in greatest diameter, located 0.2 cm inferior to the first nodule and 0.2 cm in the blue inked margin. A third nodule measuring 0.3 cm in greatest diameter is noted immediately 0.8 cm lateral. The remaining thyroid parenchyma is red tan. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule

N2 -second and third described nodule

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
4	IS	4
4	LL	4
3	N	3
1	N2	2
2	RL	4

Source: NCI Genomic Data Commons file a46e590d-423f-49c5-89ce-2dbbdefd9174 (TCGA-DJ-A4V4.E46B404D-E817-4D5F-9F1D-9E459DF09D11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).